Somatic mutation profile of tumor specimen TCGA-B1-A657-01A (aliquot TCGA-B1-A657-01A-11D-A31X-10) from TCGA case TCGA-B1-A657, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 54.2 years (19,806 days).
Specimen TCGA-B1-A657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e2a5f68-4ed0-4169-a1d9-91e57f4cf8ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-A657-10A (Blood Derived Normal), aliquot TCGA-B1-A657-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18c30e8e-7fc1-4936-9cd2-88aff7cfda22

The open-access MAF lists 80 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 19, Frame Shift Del 7, In Frame Ins 1, Splice Site 1, Intron 1, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4B | c.3031T>A p.F1011I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.942); catalogued as COSV51606194; called by muse, mutect2, varscan2
- ARID5A | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV62591358; called by muse, mutect2, varscan2
- CCDC178 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 143/412 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.052); catalogued as rs899157038, COSV55781428; called by muse, mutect2, varscan2
- CCDC87 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1412073230, COSV59579636; called by muse, mutect2, varscan2
- CERS5 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV58189558; called by muse, mutect2, varscan2
- CLEC18A | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55344982; called by muse, mutect2, varscan2
- CLNK | c.766A>C p.N256H | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV57017299; called by muse, mutect2, varscan2
- DAG1 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV58185313; called by muse, mutect2, varscan2
- DEFB118 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53620692; called by muse, mutect2, varscan2
- DENND4B | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57843869; called by muse, mutect2, varscan2
- DNAH8 | c.8268A>C p.E2756D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV59459305; called by muse, mutect2, varscan2
- DNAJC17 | c.37T>C p.Y13H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54540972; called by muse, mutect2, varscan2
- EXOC1 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62120862; called by muse, mutect2, varscan2
- FAM135A | c.3314A>G p.Y1105C (on ENST00000370479 / NM_001351599.1; = p.Y892C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758181850, COSV52054073; called by muse, mutect2, varscan2
- FBN3 | c.3213C>T p.D1071= | Splice Region (SNP) | VAF 11/26 reads (42%) | catalogued as rs773284996, COSV54464850; called by muse, mutect2, varscan2
- FBXO46 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV58349042; called by muse, mutect2, varscan2
- GPR137C | c.847T>A p.W283R | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58705739; called by muse, mutect2, varscan2
- ITGAM | c.2176C>A p.P726T (on ENST00000648685 / NM_001145808.2; = p.P725T on NM_000632.4) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54938793; called by muse, mutect2, varscan2
- JPH3 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as rs757427388, COSV52466910; called by muse, mutect2, varscan2
- KIAA2026 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52390152; called by muse, mutect2, varscan2
- KLHL11 | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1045287072, COSV59862397; called by muse, mutect2, varscan2
- LPIN2 | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1390304788, COSV55241077; called by muse, mutect2, varscan2
- NBEA | c.4877T>G p.F1626C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.121); catalogued as COSV59797696; called by muse, mutect2, varscan2
- NEO1 | c.3736C>A p.P1246T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1447908887, COSV56073933; called by muse, mutect2, varscan2
- NKX2-5 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61299455; called by muse, mutect2, varscan2
- PARP1 | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV64691127; called by muse, mutect2, varscan2
- PIF1 | c.813T>A p.F271L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51422980; called by muse, mutect2, varscan2
- PIM3 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV62259960; called by muse, mutect2
- PTPRR | c.828A>T p.L276F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.347); catalogued as COSV51737191; called by muse, mutect2, varscan2
- RABL6 | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61037062; called by muse, mutect2, varscan2
- RAI2 | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58965115; called by muse, mutect2
- SCRIB | c.1278T>A p.D426E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57589354; called by muse, mutect2, varscan2
- SLC9A6 | c.1180T>A p.F394I | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65788355; called by muse, mutect2, varscan2
- SNX12 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.886); catalogued as COSV52145896, COSV52145954; called by muse, mutect2, varscan2
- SRP14 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV51115736; called by muse, mutect2
- SUSD2 | c.343T>A p.C115S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54084545; called by muse, mutect2
- SYCE1 | c.263T>A p.L88Q (on ENST00000343131 / NM_001143764.3; = p.L52Q on NM_130784.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58218041; called by muse, mutect2, varscan2
- SYCE1 | c.262C>A p.L88M (on ENST00000343131 / NM_001143764.3; = p.L52M on NM_130784.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV58218055; called by muse, mutect2, varscan2
- THSD7A | c.1477T>G p.L493V | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV70267350; called by muse, mutect2, varscan2
- TLK2 | c.1524C>A p.H508Q (on ENST00000326270 / NM_001284333.2; = p.H486Q on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 296/607 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.943); catalogued as rs866444617, COSV58302364; called by muse, mutect2, varscan2
- TMED4 | c.193A>C p.K65Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs927863803, COSV56942113; called by muse, mutect2, varscan2
- TPX2 | c.2240G>T p.C747F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55920547; called by muse, mutect2, varscan2
- TTN | c.74401A>G p.T24801A (on ENST00000591111; = p.T17377A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/58 reads (69%) | PolyPhen benign (0.373); catalogued as COSV60160232; called by muse, mutect2, varscan2
- USP13 | c.1544T>A p.I515N | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.449); catalogued as COSV55867270; called by muse, mutect2, varscan2
- USP46 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV71512991; called by muse, mutect2, varscan2
- XRCC2 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV63770660; called by muse, mutect2, varscan2
- ZFHX3 | c.3179T>G p.V1060G | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.684); catalogued as COSV51724019; called by muse, mutect2, varscan2
- ZNF474 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); catalogued as COSV56946572; called by muse, mutect2, varscan2
- ZNF597 | c.406T>A p.L136I | Missense Mutation (SNP) | VAF 117/198 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.314); catalogued as COSV57084778; called by muse, mutect2, varscan2
- ANTXR2 | c.515del p.S172Mfs*38 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | called by mutect2, pindel, varscan2
- C1orf112 | c.1151del p.F384Sfs*20 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- CCSAP | c.719_720del p.S240Cfs*47 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by pindel, varscan2
- CHCHD3 | c.433dup p.L145Pfs*3 | Frame Shift Ins (INS) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- DLEC1 | c.613_615dup p.H205dup | In Frame Ins (INS) | VAF 37/83 reads (45%) | called by mutect2, pindel, varscan2
- LIMD1 | c.1770_1772+16del p.X590_splice | Splice Site (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- PNPLA8 | c.1191del p.G398Efs*15 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- PTEN | c.330del p.Q110Hfs*3 | Frame Shift Del (DEL) | VAF 54/223 reads (24%) | called by mutect2, pindel, varscan2
- SHB | c.1430del p.S477Mfs*30 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | called by mutect2, pindel, varscan2
- SIRT4 | c.755_757delinsC p.E252Afs*42 | Frame Shift Del (DEL) | VAF 25/99 reads (25%) | called by pindel, varscan2*
- COL22A1 | c.2634G>T p.L878= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57344543; called by muse, mutect2, varscan2
- DLG1 | c.516T>A p.T172= | Silent (SNP) | VAF 89/358 reads (25%) | catalogued as COSV58385819; called by muse, mutect2, varscan2
- F13B | c.1563A>G p.K521= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV66374528; called by muse, mutect2, varscan2
- FAM20C | c.342C>T p.A114= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV58235027; called by muse, varscan2
- KIF18B | c.1242G>A p.Q414= (on ENST00000593135 / NM_001265577.2; = p.Q426= on NM_001264573.2) | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100192177, COSV59274253; called by muse, mutect2, varscan2
- KLHL11 | c.1353C>A p.V451= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as COSV59862405; called by muse, mutect2, varscan2
- LRP6 | c.2937C>G p.L979= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as rs1337666976, COSV53788003; called by muse, varscan2
- MBNL1 | c.741C>T p.I247= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV56831239; called by muse, mutect2, varscan2
- MFAP1 | c.666G>A p.Q222= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV51039549; called by muse, mutect2, varscan2
- PITPNM1 | c.882C>T p.P294= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV62708670; called by muse, mutect2, varscan2
- PML | c.1545G>A p.K515= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV51449004; called by muse, mutect2, varscan2
- PPARG | c.636G>C p.R212= (on ENST00000287820 / NM_015869.5; = p.R182= on NM_005037.7) | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV55143539; called by muse, mutect2
- PPP1R15B | c.1488T>C p.I496= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV65816020; called by muse, mutect2, varscan2
- PVR | c.1131C>T p.H377= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV51823605; called by muse, mutect2
- SECISBP2L | c.1650T>A p.S550= (on ENST00000559471 / NM_001193489.2; = p.S505= on NM_014701.4) | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as COSV55935496; called by muse, mutect2, varscan2
- SHCBP1L | c.264G>C p.A88= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV62355655; called by muse, mutect2, varscan2
- SLC28A1 | c.1161G>A p.P387= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs754164862, COSV54481132; called by muse, mutect2, varscan2
- THBS3 | c.345G>A p.A115= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs767301739, COSV57427167; called by muse, mutect2, varscan2
- ZNF646 | c.5040C>T p.T1680= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV54925207; called by muse, mutect2, varscan2
- CORO6 | c.-210G>A | 5'UTR (SNP) | VAF 54/105 reads (51%) | catalogued as COSV99281347; called by muse, mutect2, varscan2
- FGFR4 | c.1252-22A>G | Intron (SNP) | VAF 36/80 reads (45%) | catalogued as COSV99448733; called by muse, mutect2, varscan2
